Gene-level copy-number profile of tumor specimen HCM-BROD-0557-C43-06A from HCMI case HCM-BROD-0557-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 31.6 years (11,559 days).
Specimen HCM-BROD-0557-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 707f511e-d9ba-40a7-8cd7-4fc1ad5072be.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0557-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/a0586615-d70a-4f18-9b4d-339126fad48f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 29; copy number 2: 9,470; copy number 3: 4,347; copy number 4: 35,854; copy number 5: 5,808; copy number 6: 2,456; copy number 7: 873; copy number 8: 44; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–23,438,700, 20 genes (within-gene range 0–4): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr9:125,194,649–125,195,821, 1 gene: RPSAP76.
- chr10:87,341,685–87,357,882, 1 gene (within-gene range 0–2): LINC00863.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,602,360–55,666,195, 4 genes, copy number 9: OR4C11, OR4P4, OR4S2, OR4C6.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
